Gene-level copy-number profile of tumor specimen TCGA-66-2759-01A from TCGA case TCGA-66-2759, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 66.5 years (24,287 days).
Specimen TCGA-66-2759-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.d900a387-726e-40da-8186-bdd3c338b67b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-66-2759-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0f348939-6faa-4ff3-8962-a2b7b77bc2b8

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 156; copy number 1: 2,090; copy number 2: 12,298; copy number 3: 19,880; copy number 4: 13,152; copy number 5: 6,871; copy number 6: 2,749; copy number 7: 136; copy number 8: 484; copy number 9: 1,541; copy number 10: 231; copy number 12: 12; copy number 14: 26; copy number 15: 89; copy number 16: 9; copy number 18: 87; copy number 26: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-66-2759-01A-01D-1969-01): tumor purity 0.5, ploidy 3.31, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 156 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,658,309–25,678,440, 81 genes (broad region; genes not listed).
- chr13:53,207,831–53,801,489, 1 gene (within-gene range 0–1): AL356295.1.
- chr13:53,345,211–63,513,393, 74 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,617 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:86,362,132–86,496,996, 2 genes, copy number 9: RN7SKP284, LINC02070.
- chr3:91,356,755–198,222,513, 1,802 genes, copy number 8–12 (broad region; genes not listed).
- chr6:61,679,961–68,635,161, 50 genes, copy number 9 (within-gene range 3–9): KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1, SLC25A51P1, ADH5P4, NUFIP1P1, AL450336.1, RNU7-66P, AL591004.1, AL365503.1, RNA5SP208, RNU6-280P, Y_RNA, AL713998.1, AL713998.3, AL713998.4, AL713998.2, AL646090.2, AL646090.1, AL593844.1, LINC02549, AL606923.2, AL606923.1, AL391807.1.
- chr6:87,322,583–88,175,762, 21 genes, copy number 8: SMIM8, C6orf163, AL096817.1, CFAP206, AL049697.1, AL049697.2, AL049697.3, ST13P16, SLC35A1, RNU6-444P, RARS2, ORC3, AKIRIN2, AL133211.1, Y_RNA, RN7SL183P, AL590392.1, AL136096.1, SPACA1, CNR1, AL121835.2.
- chr6:89,254,464–90,587,072, 27 genes, copy number 7: GABRR2, TUBB3P1, UBE2J1, RRAGD, NACAP7, ANKRD6, RN7SL11P, AL159174.1, LYRM2, MDN1, AL096678.1, DNAJC19P6, PIMREGP3, CASP8AP2, Y_RNA, RPL22P14, AL353692.1, GJA10, Y_RNA, BACH2, AL121787.1, RN7SKP110, AL158136.1, AL117342.1, AL132996.1, MIR4464, MAP3K7.
- chr6:108,294,991–108,526,796, 1 gene, copy number 9 (within-gene range 6–9): AFG1L.
- chr6:108,359,084–111,231,194, 62 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr6:124,644,434–125,932,034, 12 genes, copy number 8 (within-gene range 4–8): RNF217-AS1, RNF217, TPD52L1, HDDC2, AL121938.1, AL450332.1, AL365259.1, LINC02523, HEY2, NCOA7, NCOA7-AS1, RN7SKP56.
- chr6:133,821,147–137,045,180, 72 genes, copy number 8–10 (broad region; genes not listed).
- chr8:34,784,028–39,284,917, 91 genes, copy number 15–26 (within-gene range 4–26) (broad region; genes not listed).
- chr9:5,334,930–6,507,054, 25 genes, copy number 8 (within-gene range 3–8): RLN1, AL135786.2, AL135786.1, PLGRKT, RNF152P1, CD274, AL162253.2, PDCD1LG2, AL162253.1, RIC1, AL136980.1, ERMP1, AK4P4, KIAA2026, MLANA, MIR4665, RANBP6, AL162384.1, GTF3AP1, IL33, AL360221.1, SELENOTP1, TPD52L3, UHRF2, AL133480.1.
- chr9:25,780,032–27,543,902, 25 genes, copy number 10 (within-gene range 0–10): LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1.
- chr11:63,137,867–63,500,610, 9 genes, copy number 10 (within-gene range 3–10): SLC22A10, SLC22A25, AP001880.2, CCND2P1, AP001880.1, SLC22A9, PLAAT5, AP000484.1, AP001591.1.
- chr11:91,382,909–93,241,168, 25 genes, copy number 7: AP002791.1, LINC02756, TUBB4BP4, AP002799.1, RPL7AP57, NDUFB11P1, FAT3, PGAM1P9, AP000722.1, RPS3AP42, AP003718.1, LINC02746, AP003171.2, SNRPGP16, AP003171.1, MTNR1B, RPL26P31, AP002371.1, AP003072.4, SLC36A4, AP003072.2, AP003072.5, AP003072.3, AP003072.1, AP003969.1.
- chr12:90,576,402–90,889,917, 4 genes, copy number 7 (within-gene range 3–7): LINC02822, AC084365.1, AC112481.2, AC112481.1.
- chr19:30,219,666–31,147,981, 8 genes, copy number 16: AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1.
- chr19:31,167,457–31,225,143, 1 gene, copy number 16: LINC01791.
- chr19:33,217,817–40,796,943, 380 genes, copy number 7–18 (within-gene range 2–18) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,090. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
